Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4183, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4183-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST: Specimen type: Total gastrectomy. Tumor Site: Cardia. Tumor configuration: Ulcerating. Tumor size: 8.0 x 7.0 x 1.5 cm. Histologic type: Adenocarcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Serosa (visceral peritoneum). Lymph nodes: 2 of 8 lymph nodes positive for metastasis. Margins: Not specified. Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

STOMACH TISSUE CHECKLIST: Specimen type: Total gastrectomy. Tumor Site: Cardia. Tumor configuration: Ulcerating. Tumor size: 8.0 x 7.0 x 1.5 cm. Histologic type: Adenocarcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Serosa (visceral peritoneum). Lymph nodes: 2 of 8 lymph nodes positive for metastasis. Margins: Not specified. Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 7327a1de-a5d0-4957-a86a-9e9b6160ad7c (TCGA-BR-4183.0C28B0A4-9B7E-4FB1-B932-254E871B6B3C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).